Surgical pathology report (de-identified scan), TCGA case TCGA-FX-A3NJ, project TCGA-SARC (Sarcoma), tissue source site International Genomics Consortium, specimen TCGA-FX-A3NJ-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED]
DOB/Gender: [REDACTED] (Age: M
Location: [REDACTED]
Soc. Sec. #: [REDACTED]
Physician(s): [REDACTED]

Path No.: [REDACTED]
Client: [REDACTED]
Collected: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]
Hosp #: [REDACTED]

Pre-Operative/Clinical History

Peritoneal low grade sarcoma

Specimen(s) Received

A: RIGHT PERIRENAL MASS
B: CELIAC MASS
C: MARGIN OF CELIAC MASS

Gross Description

Specimen A, received fresh from the OR labeled right perirenal mass:

Specimen type: Marginal.

Specimen size/description: Consists of a 65 gm, 7.0 x 6.0 x 5.5 cm well-circumscribed mass. The external surface shows a nodular pattern with multiple thickened fibrous adhesions. The margin is inked black. The cut surfaces show solid, whorled, tan-white tissue.

Lesion site: Perirenal mass.

Lesion depth:
Superficial: Not involved.
Deep: Involved.

Lesion size: 7.0 x 6.0 x 5.5 cm.

Lesion margins: Lesion abuts the margin of resection.

Lesion description: See above.

Pre-resection treatment: No therapy.

Necrosis: Absent.

ICD-0-3
leiomyosarcoma, NOS 8890/3
Site: retroperitoneum C48.0

lw
1/17/12

A portion of the specimen is submitted for frozen section analysis.

Gross photos are taken.

Representative sections are submitted as follows:

(A1FS) Frozen section
(A2-A10) Additional tissue.

[page 2 of 3]
HISTOLOGY REPORT

Specimen B, received fresh labeled celiac mass, consists of a 1.5 x 1.5 x 0.3 cm aggregate of tan tissue fragments. The cut surfaces show a yellow to bright red solid surface. A portion of the specimen is submitted for frozen section analysis.

The specimen is entirely submitted as follows:

(B1FS te) Frozen section
(B2, B3 te) Additional tissue.

Specimen C, received in formalin labeled margin of celiac mass, consists of a 1.5 x 0.5 x 0.3 cm tan cylindrical tissue fragment. (C1 te).

Intraoperative Consultation

Specimen A, frozen section diagnosis: "smooth muscle neoplasm, cannot exclude low grade leiomyosarcoma" is rendered by Dr.

Specimen B, frozen section diagnosis: "negative as sampled" is rendered by Dr.

Microscopic Description

Summary of Pathologic Findings Soft Tissue Sarcoma Resection

Procedure: Marginal resection.

Tumor site: Retroperitoneum, right perinephric region.

Macroscopic tumor depth:
Superficial: Not involved.
Deep: Involved.

Tumor size: At least 7.0 cm.

Histologic type (WHO Classification): Leiomyosarcoma.

Mitotic rate: 5/10hpf (field area of 0.23 mm²).

Ancillary studies: Not performed on current specimen. See immunohistochemical stain results from previous diagnostic core biopsy.

Pre-resection treatment: No therapy.

Treatment effect: Not applicable.

Necrosis: Absent. There is central degenerative change and hemorrhage consistent with the prior biopsy.

Histologic grade: : Low grade.

Margin status: Margins not involved by sarcoma. Marginal resection with tumor completely surrounded by a thin fibrous membrane ranging in thickness from 0.1-0.5 cm.

Venous/lymphatic (large/small vessel invasion): Absent.

Pathologic staging (pTNM): pT2b N0

Additional pathologic findings: None.

[page 3 of 3]
Diagnosis

- A) RIGHT PERIRENAL SOFT TISSUE MASS, MARGINAL EXCISION:
LOW GRADE LEIOMYOSARCOMA, 7.0 CM (SEE DESCRIPTION).
- B) CELIAC MASS, EXCISION:
BENIGN LYMPH NODE.
- C) MARGIN OF CELIAC MASS, BIOPSY:
BENIGN FIBROADIPOSE AND LYMPH NODE TISSUE.

***Electronically Reviewed and Signed Out By

Intradepartmental Consult

Dr.

CPT Code(s)

88331
A: 88307, 88342
B: 88331, 88305
C: 88305

Procedures/Addenda

IMMUNOHISTOCHEMISTRY ADDENDUM

Addendum Comment

Immunohistochemical stain for KI-67 was performed and shows a mildly elevated proliferation rate of approximately 10-20%.

***Electronically Reviewed and Signed Out By

Source: NCI Genomic Data Commons file c21c9818-3634-43d7-b0b0-19d9f0374600 (TCGA-FX-A3NJ.BF4B953D-7BE2-47DF-8F1C-EF022291CE52.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).